Surgical pathology report (de-identified scan), TCGA case TCGA-CU-A5W6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site UNC, specimen TCGA-CU-A5W6-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9

Diagnosis:

A: Bladder and prostate, cystoprostatectomy

9w 3/18/13

Procedure: Cystoprostatectomy

Tumor histologic type: Invasive urothelial carcinoma

Tumor histologic grade (WHO classification): High grade

Microscopic tumor size (greatest dimension): 3.4 cm (mass A),
1.2 cm (mass B)

Microscopic extent of invasion: Tumor invades through the
muscularis propria

Tumor site/focality of tumor: Multifocal; tumor involves the
right lateral wall of the bladder, left lateral wall and dome of
bladder.

Angiolymphatic space invasion: Present

Associated epithelial lesions: Present. Urothelial dysplasia is
present in the left UVJ, carcinoma in situ is present within
prostatic ducts (A16).

Ureters: No tumor identified

Histologic assessment of surgical margins:

Ureter, left: Negative

Ureter, right: Negative

Urethra: Negative

Paravesicular soft tissue: Negative

Other significant findings: Biopsy site changes, granulomas in
prostatic urethra consistent with prior biopsy

Lymph nodes: Eight lymph nodes negative for carcinoma (0/8)

Diagnoses of other organs or structures: Prostate glands focally
involved with urothelial carcinoma in situ, no prostatic stromal
invasion identified

AJCC Pathologic TNM Stage: pT3 pN0

[page 2 of 4]
NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph nodes, left pelvic, regional node dissection

- Two lymph nodes negative for carcinoma (0/2)

C: Lymph nodes, right pelvic, regional node dissection

- Six lymph nodes negative for carcinoma (0/6)

Clinical History:

-year-old male with bladder cancer.

Gross Description:

Received are three appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen(s) received: cystoprostatectomy

Size of overall specimen: The bladder measures 6.0 x 5.8 x 3.8 cm and the prostate measures 4.7 x 4.2 x 3.0 cm.

Orientation: The right perivesicular tissue and right prostate is inked blue, and left perivesicular tissue and left prostate is inked black. The distal urethral margin is inked yellow.

Tumor size: Mass A measures 3.4 x 2.2 x 1.2 cm. Mass B measures 1.2 x 1.1 x 0.3 cm.

Tumor description: Both Mass A and Mass B consists of yellow/tan ulcerating and slightly necrotic appearing masses.

Tumor location: Mass A is located in the left lateral wall and extends to the dome of the bladder. Mass B is located in the right lateral part of the bladder wall.

[page 3 of 4]
Distance of tumor to margins: Mass A is 4.1 cm from the distal urethral margin, 1.3 cm away from the left distal ureter margin, and 5.2 cm from the right distal ureter margin. Mass A is 0.3 cm from the black inked soft tissue margin. Mass B is 4.2 cm from the distal urethral margin, 3.1 cm from the right distal ureteral margin, and 5.1 cm from the left distal ureteral margin. Mass B is 2.4 cm from the blue inked soft tissue margin.

Other mucosal lesions: none identified

Description of other organs or structures: The prostate consists of tan/white fibrous tissue with no masses or lesions identified grossly.

Digital photograph taken: not taken

Tissue submitted for special investigation: Tumor and normal were given to Tissue Procurement.

Block Summary:

- A1 - distal urethral margin, en face
- A2 - distal right ureteral margin, en face
- A3 - distal left ureteral margin, en face
- A4 - right vas deferens margin
- A5 - left vas deferens margin
- A6 - right ureterovesicular junction
- A7 - left ureterovesicular junction
- A8 - trigone
- A9 - representative full thickness section of Mass A with black inked soft tissue margin
- A10,A11 - additional sections of Mass A
- A12,A13 - representative sections of Mass B including blue inked soft tissue margin
- A14,A15 - sections of uninvolved bladder
- A16,A17 - representative sections of right posterior prostate
- A18,A19 - representative sections of left posterior prostate

Container B is additionally labeled "left pelvic lymph nodes." It holds an aggregate of yellow/tan fibrofatty tissue measuring 5.5 x 2.2 x 0.5 cm. The tissue is dissected for lymph node candidates and two lymph nodes are identified with largest diameters of 0.3 and 3.5 cm respectively.

Block Summary:

[page 4 of 4]
B1,B2 - one lymph node candidate, bisected
B3 - one lymph node candidate
B4 - remaining tissue,

Container C is additionally labeled "right pelvic lymph nodes."
It holds an aggregate of yellow/tan fibrofatty tissue measuring
4.5 x 2.1 x 1.0 cm. The tissue is dissected for lymph node
candidates, and three lymph node candidates are identified
ranging in largest diameter from 0.3 to 2.8 cm.

Block summary:

C1 - two lymph node candidates
C2,C3 - one lymph node candidate, bisected
C4 - remaining tissue,

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file 5ad5eae9-2428-4585-8f72-3875650ca3c8 (TCGA-CU-A5W6.16450945-2661-4167-84D2-9469077B4CDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).